Somatic mutation profile of tumor specimen BA2166D (aliquot aq-BA2166D) from BEATAML1.0 case 2357, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.5 years (25,733 days).
Specimen BA2166D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e267929-3401-40b2-90cd-7daed7aae9b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2129D (Solid Tissue Normal), aliquot aq-BA2129D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b2d4744-1105-4a43-82f3-65c83bcbfba6

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, 3'UTR 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1760A>T p.H587L | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as CD993247; called by muse, mutect2
- ANO3 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs376935363; called by mutect2, varscan2
- DMRTA1 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs771730054; called by muse, mutect2, varscan2
- MYBPHL | c.302T>A p.V101E | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs867815860; called by muse, mutect2, varscan2
- STAG2 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | catalogued as COSV54372356; called by muse, mutect2
- ANKRD16 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, mutect2
- CLEC19A | c.255-1G>A p.X85_splice | Splice Site (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2, varscan2
- DYRK3 | c.924C>A p.S308R | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MSR1 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAX6 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF183 | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYT12 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- YLPM1 | c.4004C>A p.P1335Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX60 | c.2472G>A p.V824= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- DLG2 | c.1206T>A p.T402= | Silent (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.*1762C>A | 3'UTR (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
